Somatic mutation profile of tumor specimen BA2809D (aliquot aq-BA2809D) from BEATAML1.0 case 2301, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.9 years (25,886 days).
Specimen BA2809D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0d5b1b9-e89b-4951-a5e8-97acba8c13fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2458D (Solid Tissue Normal), aliquot aq-BA2458D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b65fe7d2-7179-4ce3-887f-4fdb0c62834f

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KALRN | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs926123706, COSV53752228; called by muse, mutect2
- MYH13 | c.5641T>A p.S1881T | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52837022, COSV99353665; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by mutect2, varscan2
- TRRAP | c.11164G>T p.D3722Y (on ENST00000359863 / NM_001244580.1; = p.D3693Y on NM_003496.3) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100705490; called by muse, mutect2
- PAN3 | c.2642C>A p.A881E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.194); called by muse, mutect2
- GRID2IP | c.3444G>T p.G1148= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- AC092865.4 | chr12:8390653 G>T | 5'Flank (SNP) | VAF 6/24 reads (25%) | catalogued as rs190105354; called by muse, varscan2
